Somatic mutation profile of tumor specimen MMRF_1474_1_BM_CD138pos (aliquot MMRF_1474_1_BM_CD138pos_T1_KAS5U_L01925) from MMRF case MMRF_1474, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 27.8 years (10,136 days).
Specimen MMRF_1474_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d25d42b-0068-403c-9b85-23690953638f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1474_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1474_1_PB_Whole_C2_KAS5U_L01935; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f101ff27-7b57-4d7c-92be-9584b9fb4aa8

The open-access MAF lists 93 somatic variants for this specimen: 35 protein-altering or splice-affecting, 20 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 20, 3'UTR 17, Intron 13, 3'Flank 5, 5'UTR 2, Frame Shift Del 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.659G>C p.S220T | Missense Mutation (SNP) | VAF 101/202 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.084); catalogued as rs1366155208; called by muse, mutect2, varscan2
- CCL13 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs187454526, COSV99861674; called by muse, varscan2
- CYP2J2 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs144581123, COSV64606855; called by muse, mutect2, varscan2
- DDRGK1 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV63227185; called by muse, mutect2, varscan2
- FLT1 | c.3680C>T p.T1227I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs1238611113, COSV99165521; called by muse, mutect2, varscan2
- GATA3 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1266983268, COSV60516000; called by muse, mutect2, varscan2
- IGHV2-70 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs373390524; called by muse, varscan2
- IGHV2-70 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs371562118; called by muse, varscan2
- IGHV2-70 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs373084365; called by muse, varscan2
- IGKV1-5 | c.63A>T p.K21N | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs377188226; called by muse, varscan2
- IGLV3-1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183724895; called by muse, varscan2
- IGLV3-1 | c.302A>G p.E101G | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs532827838; called by muse, mutect2, varscan2
- MAP3K14 | c.493del p.L165Sfs*36 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as COSV60922940; called by pindel, varscan2
- OGT | c.2003C>T p.T668M | Missense Mutation (SNP) | VAF 30/30 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65479659; called by muse, mutect2, varscan2
- RYR1 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 218/448 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757399861, COSV62100636, COSV62112455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC1A2 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1360598399, COSV99554270; called by muse, mutect2, varscan2
- SNAPC2 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV99683978; called by muse, mutect2, varscan2
- ZNF98 | c.305dup p.N102Kfs*12 | Frame Shift Ins (INS) | VAF 92/216 reads (43%) | catalogued as rs757764317; called by mutect2, varscan2
- C1QL2 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- CBLB | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD200R1 | c.780C>A p.F260L (on ENST00000471858 / NM_170780.3; = p.F283L on NM_138806.4) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.382); called by muse, mutect2
- CFAP52 | c.536A>T p.N179I | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CRAT | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.15170T>A p.I5057K | Missense Mutation (SNP) | VAF 93/135 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- LAMC2 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAP3K14 | c.410del p.K137Sfs*64 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | called by pindel, varscan2
- NAA11 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NEK1 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- PCDHA12 | c.2287A>G p.S763G | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- SHOC1 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SHROOM3 | c.5903C>A p.A1968D | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SLC28A2 | c.1615C>A p.L539I | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZFY | c.1957A>G p.T653A | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF341 | c.1616T>C p.V539A (on ENST00000375200 / NM_001282935.1; = p.V532A on NM_032819.4) | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABL2 | c.717C>T p.S239= (on ENST00000502732 / NM_007314.4; = p.S224= on NM_005158.5) | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- AL592490.1 | c.2085G>A p.R695= | Silent (SNP) | VAF 42/123 reads (34%) | called by muse, mutect2, varscan2
- ATG7 | c.1914C>T p.P638= | Silent (SNP) | VAF 34/273 reads (12%) | catalogued as rs774917196, COSV61612664; called by muse, mutect2, varscan2
- C3orf33 | c.252C>T p.R84= (on ENST00000340171 / NM_001308229.2; = p.R41= on NM_173657.2) | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- CSRNP1 | c.1338C>T p.G446= | Silent (SNP) | VAF 47/136 reads (35%) | called by muse, mutect2, varscan2
- DMRT1 | c.909C>T p.S303= | Silent (SNP) | VAF 62/242 reads (26%) | catalogued as rs534737562, COSV66524957; called by muse, mutect2, varscan2
- FBN2 | c.5118G>A p.G1706= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs1284156837; called by muse, mutect2, varscan2
- GABRD | c.1203G>A p.T401= | Silent (SNP) | VAF 40/71 reads (56%) | catalogued as rs1348578642, COSV66080447; ClinVar: likely benign; called by muse, mutect2, varscan2
- H4C6 | c.198G>A p.V66= | Silent (SNP) | VAF 71/141 reads (50%) | catalogued as rs760722568, COSV66685476, COSV66685716; called by muse, mutect2, varscan2
- HAPLN1 | c.714C>T p.Y238= | Silent (SNP) | VAF 61/208 reads (29%) | catalogued as rs200074127, COSV57148848; called by muse, mutect2, varscan2
- IGHV2-70 | c.90G>A p.L30= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as rs564942249; called by muse, varscan2
- NR2F2 | c.513C>A p.P171= | Silent (SNP) | VAF 64/330 reads (19%) | called by muse, mutect2, varscan2
- NUP155 | c.1158G>T p.T386= (on ENST00000231498 / NM_153485.3; = p.T327= on NM_004298.4) | Silent (SNP) | VAF 68/243 reads (28%) | called by muse, mutect2, varscan2
- PTCH1 | c.141G>C p.R47= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs587780693; ClinVar: likely benign; called by muse, mutect2, varscan2
- RTL1 | c.1824C>T p.Y608= | Silent (SNP) | VAF 61/110 reads (55%) | catalogued as rs764643262, COSV101128236, COSV66016820; called by muse, mutect2, varscan2
- SBK3 | c.624C>T p.L208= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- SENP8 | c.243C>G p.P81= | Silent (SNP) | VAF 31/322 reads (10%) | called by muse, mutect2, varscan2
- SGK1 | c.777C>T p.G259= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- TACC2 | c.1245A>G p.E415= | Silent (SNP) | VAF 27/118 reads (23%) | called by muse, mutect2, varscan2
- TRIO | c.2268C>T p.H756= | Silent (SNP) | VAF 41/251 reads (16%) | catalogued as rs537368455; called by muse, mutect2, varscan2
- ACTR8 | c.1568-131G>A | Intron (SNP) | VAF 11/46 reads (24%) | catalogued as rs1026520095, COSV99213781; called by muse, mutect2
- ARF1 | chr1:228103355 C>A | 3'Flank (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- ATP2A1 | c.118+115G>A | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- CCL19 | c.-32A>T | 5'UTR (SNP) | VAF 7/153 reads (5%) | called by muse, mutect2
- CHST3 | c.*3169C>T | 3'UTR (SNP) | VAF 41/97 reads (42%) | catalogued as rs1013596149; called by muse, mutect2, varscan2
- COL4A2 | c.478-57G>A | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as rs1043977516; called by muse, varscan2
- CTNNB1 | c.*903T>A | 3'UTR (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- CYFIP1 | chr15:22868273 T>C | 3'Flank (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- DNAJA2 | c.138+100C>T | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as rs947627469; called by muse, mutect2
- DOCK4 | c.*464G>T | 3'UTR (SNP) | VAF 69/211 reads (33%) | called by muse, mutect2, varscan2
- FAM210B | c.186+1298A>G | Intron (SNP) | VAF 42/153 reads (27%) | called by muse, mutect2, varscan2
- FIGN | c.*5616G>T | 3'UTR (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- GABRA2 | c.*345T>G | 3'UTR (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- GSK3B | c.*3181G>C | 3'UTR (SNP) | VAF 21/92 reads (23%) | called by muse, varscan2
- KHDRBS3 | c.208-102T>C | Intron (SNP) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- LHX2 | chr9:124007986 C>T | 5'Flank (SNP) | VAF 14/344 reads (4%) | called by muse, mutect2
- NBEA | c.*631G>A | 3'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- NEDD1 | c.*1029A>C | 3'UTR (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- NEURL4 | chr17:7315627 G>A | 3'Flank (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- NOX4 | c.*603C>T | 3'UTR (SNP) | VAF 97/619 reads (16%) | catalogued as rs1186376617; called by muse, mutect2, varscan2
- NPY2R | chr4:155217077 G>T | 3'Flank (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- ORAI2 | c.*1726A>G | 3'UTR (SNP) | VAF 12/20 reads (60%) | called by muse, varscan2
- PAX5 | c.-5T>C | 5'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- PCARE | c.*541G>A | 3'UTR (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- PDE3A | c.*3570C>T | 3'UTR (SNP) | VAF 50/110 reads (45%) | catalogued as rs551352087; called by muse, mutect2, varscan2
- PPARGC1A | c.234+190dup | Intron (INS) | VAF 36/81 reads (44%) | called by mutect2, varscan2
- RALGDS | c.2455-38G>C | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2
- RANBP6 | c.*518G>C | 3'UTR (SNP) | VAF 27/198 reads (14%) | called by muse, mutect2
- SCAMP2 | c.*1048C>A | 3'UTR (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- SIK3 | c.434+3795T>G | Intron (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- SLC12A6 | c.*243del | 3'UTR (DEL) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- SLC37A4 | c.985-247G>A | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- SNRPN | c.3+317G>A | Intron (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- TFAP2A | chr6:10397895 del TGT | 3'Flank (DEL) | VAF 26/70 reads (37%) | catalogued as rs1454553382; called by pindel, varscan2
- TRAF3IP3 | c.915+44G>A | Intron (SNP) | VAF 76/155 reads (49%) | called by muse, mutect2, varscan2
- TRDN | c.*1196T>C | 3'UTR (SNP) | VAF 11/86 reads (13%) | catalogued as rs1399474495; called by muse, mutect2, varscan2
- WDR37 | c.*1419G>A | 3'UTR (SNP) | VAF 3/50 reads (6%) | catalogued as rs997566571; called by muse, mutect2
- ZNF890P | n.478-43C>A | Intron (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2
